Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-4614, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-4614-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LIVER, SEGMENT 3, BIOPSY -

- A. LIVER PARENCHYMA WITH TRIADITIS, CHOLESTASIS, STEATOSIS AND MICROABSCESSES.
- B. NO EVIDENCE OF MALIGNANCY.

PART 2: LIVER, SEGMENT 7, BIOPSY -

METASTATIC ADENOCARCINOMA.

PART 3: RIGHT COLON, SIGMOID COLON, URINARY BLADDER, RESECTION -

- A. POORLY DIFFERENTIATED ADENOCARCINOMA (3.0 CM) CIRCUMFERENTIALLY OCCUPYING THE CECUM AND EXTENDING THROUGH THE CECAL WALL INTO SIGMOID COLON AND URINARY BLADDER.
- B. PROXIMAL (ILEAL) AND DISTAL (COLONIC) MARGINS ARE NEGATIVE FOR TUMOR.
- C. PROXIMAL ILEAL AND DISTAL SIGMOID COLON MARGINS ARE NEGATIVE FOR TUMOR.
- D. ANGIOLYMPHATIC INVASION PRESENT.
- E. TWO OF 4 LYMPH NODES POSITIVE FOR METASTATIC ADENOCARCINOMA (2/4).
- F. PATHOLOGIC STAGE pT4a N1 M1.
- G. SMALL BOWEL WITH CHRONIC CROHN'S ILEITIS, INFLAMMATORY PSEUDOPOLYPS AND FOCAL LOW GRADE DYSPLASIA.

PART 4: NEW ANTERIOR BLADDER MARGIN, BIOPSY -

PORTION OF URINARY BLADDER NEGATIVE FOR MALIGNANCY.

PART 5: RIGHT COLON, SIGMOID COLON, URINARY BLADDER REMNANT, EXCISION -

FOCI OF METASTATIC ADENOCARCINOMA.

PART 6: "PROXIMAL SIGMOID", EXCISION -

- A. UNREMARKABLE SEGMENT OF COLON.
- B. NO TUMOR IS SEEN.

PART 7: "DISTAL SIGMOID", EXCISION -

- C. UNREMARKABLE SEGMENT OF COLON.
- D. NO TUMOR IS SEEN.

PART 8: SIGMOID COLON, EXCISION -

- A. UNREMARKABLE SEGMENT OF COLON.
- B. NO TUMOR IS SEEN.

PART 9: PROXIMAL ANASTOMOSIS RING, EXCISION -

- A. UNREMARKABLE SEGMENT OF COLON.
- B. NO TUMOR IS SEEN.

PART 10: DISTAL ANASTOMOSIS RING, EXCISION -

- A. UNREMARKABLE SEGMENT OF COLON.
- B. NO TUMOR IS SEEN.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY COLON, RECTAL, APPENDIX TUMORS	
SPECIMEN TYPE:	Other: right colon, sigmoid colon and bladder
SPECIMEN LENGTH:	87 cm
TUMOR SITE:	Cecum
TUMOR CONFIGURATION:	Infiltrative
TUMOR SIZE:	Greatest dimension: 3.0 cm
	Additional dimensions: 2.5 x 1.8 cm
INTACTNESS OF MESORECTUM:	Not applicable
HISTOLOGIC TYPE:	Adenocarcinoma
HISTOLOGIC GRADE:	High-grade (poorly differentiated to undifferentiated)
PATHOLOGIC STAGING (pTNM):	pT4a
	pN1: Metastasis in 1 to 3 regional lymph nodes
	Number of nodes examined: 4
	Number of nodes involved: 2
	pM1
MARGINS:	Site(s): liver
	Proximal margin uninvolved by invasive carcinoma
	Distal margin uninvolved by invasive carcinoma
	Circumferential (radial) margin - Not applicable
	Mesenteric margin cannot be assessed
ANGIOLYMPHATIC INVASION:	Present
PERINEURAL INVASION:	Absent
TUMOR BORDER CONFIGURATION:	Infiltrating
ADDITIONAL TUMOR CHARACTERISTICS:	None
ADDITIONAL PATH FINDINGS (check all that apply):	Crohn disease

Source: NCI Genomic Data Commons file 91b34baf-12d6-4386-99ec-745248c84f69 (TCGA-AZ-4614.FC88FD70-B6F7-4130-A72E-EA2D11C9F27C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).